Somatic mutation profile of tumor specimen MBCProject_3860_T1B_WES (aliquot MBCProject_3860_T1B_WES_1) from CMI case MBCProject_3860, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 66.9 years (24,442 days).
Specimen MBCProject_3860_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f0a4a47-34dc-40ab-98c3-5ca6eaf08974.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3860_SALIVA (Saliva), aliquot MBCProject_3860_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ec9cbe1-e8d0-46ac-b555-b1826c1c7e13

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 2, 3'Flank 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV65560948; called by muse, mutect2
- PYGB | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202219219, COSV53820144; called by muse, mutect2, varscan2
- RBM15B | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV60044426; called by muse, mutect2, varscan2
- RBMXL3 | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.094); catalogued as rs781955764; called by muse, mutect2, varscan2
- CFAP44 | c.3888G>C p.Q1296H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, varscan2
- GRK6 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- KIF26A | c.5260G>T p.D1754Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TSPYL4 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- GPR141 | c.423G>A p.T141= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1192640734, COSV57734151; called by muse, mutect2, varscan2
- NPTX2 | c.1152C>T p.R384= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs748698114, COSV55716163; called by mutect2, varscan2
- NUMB | c.981C>A p.I327= (on ENST00000355058; = p.I316= on NM_003744.5) | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV61828178, COSV61830428; called by muse, mutect2, varscan2
- PGLYRP4 | c.642C>G p.V214= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- SLC35A1 | c.168A>G p.L56= | Silent (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- UBE3B | c.2982C>T p.F994= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as rs946063264; called by muse, mutect2, varscan2
- C9orf85 | c.323+1189T>G | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, varscan2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 6/48 reads (13%) | called by muse, varscan2
- TUBBP5 | n.1427C>T | RNA (SNP) | VAF 6/23 reads (26%) | catalogued as rs189844666; called by mutect2, varscan2
